Surgical pathology report (de-identified scan), TCGA case TCGA-IB-AAUS, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-AAUS-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
		Location	

Copied To

Report Patient Name
Demographics (for verification purposes)
Sex: F

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
A. Lymph node number 12 at
B. Gallbladder at
C. Lymph node number 8 at
D. Bile duct margin at
E. Whipple's specimen at
F. Pancreatic margin at
Clinical Information
Pancreatic Ca
Infectious patient: No

ICD-O-3

Adenocarcinoma, duct NOS
850013
Site: Pancreas head
625.0
7/20/14

Diagnosis

- A. Lymph Node, Number 12, Excision:
- One lymph node negative for carcinoma (0/1)
- B. Gallbladder, Cholecystectomy:
- Chronic cholecystitis
- One reactive lymph node
- Negative for malignancy
- C. Lymph Node, Number 8, Excision:
- One lymph node negative for carcinoma (0/1)
- D. Bile Duct Margin, Excision:
- Negative for malignancy
- E. Pancreas, Distal Stomach, Proximal Duodenum, Whipple's Procedure:
- Adenocarcinoma, see synoptic report and comment
- F. Pancreatic Margin, Excision:
- Adenocarcinoma is present at the margin, see comment

Reported by:

Electronically signed by:

Verified:

Synoptic Report

SPECIMEN:

Head of pancreas

Body of pancreas

Duodenum

Stomach

Common bile duct

Gallbladder

PROCEDURE:

[page 2 of 3]
Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

Uncinate process

Pancreatic body

TUMOR SIZE:

Greatest dimension: 4.0 cm

Additional dimensions: 4.0 x 3.0 cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades ampulla of Vater or sphincter of Oddi

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 14

Number involved: 2

ANCILLARY STUDIES:

Gross Description

Received are specimen containers A to F. All remissions and specimen containers are labelled with the patient's name, The cassettes and identifiers are labelled with the Surgical Number

A. The specimen is received fresh and is subsequently placed into formalin. The container is designated "A: Lymph node number 12". Specimen consists of a possible lymph node measuring 2.5 x 2.2 x 0.4 cm. Specimen is bisected. Cut surface is tan, brown, and variegated. Specimen is bisected and submitted in toto in two cassettes.

B. The specimen is received fresh and is subsequently placed into formalin. The container is designated "B: Gallbladder". Specimen consists of a grey green, intact gallbladder, measuring 10.0 x 3.5 x 1.5 cm. Serosal surface is tan and smooth. Cystic duct lymph node is identified, measuring 1.8 x 1.0 x 0.7 cm. Cystic duct is patent. Lumen contains thick dark green mucus bile. Mucosa is green and velvety. The gallbladder wall averages 0.4 cm in thickness and appears somewhat edematous. Sections are submitted as follows:

B1. cystic duct lymph node bisected and submitted in toto

B2. representative section

C. The specimen is received fresh and is subsequently placed into formalin. The container is designated "C: Lymph node number 8". Specimen consists of tan possible lymph node, measuring 2.2 x 0.8 x 0.3 cm. Specimen is bisected and submitted in toto in one cassette.

D. The specimen consists of tan tissue measuring 1.5 x 0.5 x 0.2 cm. Submitted for quick section.

The specimen is received fresh and is subsequently placed into formalin. The container is designated "D: Bile duct margin".

E. The specimen is received fresh and is subsequently placed into formalin. The container is designated "E: Whipple specimen". Specimen consists of a whipple's resection including distal stomach, measuring 4.0 cm along the lesser curvature, 5.0 cm along the greater curvature and ranging in circumference from 4.0 cm of the pylorus to 7.5 cm of the proximal margin, which was received stapled. There is a portion of pancreas, measuring 5.5 x 4.0 x 2.0 cm. The duodenum measures 22.5 cm in length and averages 4.0 cm in circumference. Attached peripancreatic soft tissue, extends to a maximum depth of 4.0 cm. Proximal margin of stomach and distal margin and received stapled. Specimen is inked as follows: vessel bed margin- green, pancreatic body- blue, uncinate process- black, anterior soft tissue surface- orange, and the posterior soft tissue surface- yellow. The common bile duct measures 5.5 cm in length and averages 1.3 cm in circumference.

There is an ill defined, firm tan mass identified within the pancreas, 4.0 x 4.0 x 3.0 cm and comes within 1.0 cm to the body margin, 0.3 cm to the uncinate margin, 1.0 cm to the anterior surface, 0.2 cm to the posterior surface, grossly extends to the vessel bed margin, 16.0 cm to the distal margin, 5.5 cm to the proximal margin and 2.5 cm to the common bile duct margin. The mass appears to involve the ampulla and pancreatic duct. There is a submucosal soft yellow nodule, located in the duodenum. The serosal surfaces

[page 3 of 3]
of the stomach and duodenum are tan, smooth and appear grossly unremarkable. Sections are submitted as follows:

- E1. common bile duct margin
- E2 to 4. proximal margin trisected
- E5/6. distal margin bisected
- E7/8. mass in relation to the ampulla
- E9 to 11. mass in relation to the vessel bed margin
- E12. mass in relation to the anterior surface with E11, E12 being a contiguous section bisected
- E13 to 15. mass in relation to the body margin
- E16/17. mass in relation to the uncinate margin and anterior surface
- E18/19. mass in relation to the posterior surface
- E20. representative section of the submucosal nodule from duodenum and the duodenum
- E21. transition from pylorus to duodenum
- E22 to 25. eight possible peripancreatic lymph nodes, ranging in size from 0.5 to 1.5 cm in maximum dimension with E22 containing four possible lymph nodes, E23 two possible lymph nodes, and E24/25 each containing one possible lymph node bisected

F. The specimen consists of a 2.5 x 2.0 x 0.5 cm friable tissue in toto for quick section.

The specimen is received fresh and is subsequently placed into formalin. The container is designated "F: Pancreatic margin".

Sample and Test Request Deficiency

D. Bile Duct Margin:

- Negative for carcinoma.

F. Pancreatic Margin:

- Negative for carcinoma.

Pathologist Comment

Sections demonstrate carcinoma at the pancreatic margin in part F. Multiple foci are better visualized in the permanent sections. In part E, the Body margin is negative. The vascular bed margin is close (0.1 cm). The anterior and posterior soft tissue surfaces are also close (<0.1 cm). The remaining margins are negative.

Fourteen lymph nodes were examined in total, from parts A, C, and E.

The following slides were shown in consultation to Dr.

E7, E9-E11, E13-E17.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file ab80e58a-67f8-4d17-ad17-7bd2196063a5 (TCGA-IB-AAUS.FCA3763B-0CCE-4EFF-ACAA-FD05281A87D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).